Gene-level copy-number profile of specimen HCM-CSHL-0853-C56-85D from HCMI case HCM-CSHL-0853-C56, project HCMI-CMDC (NCI Cancer Model Development for the Human Cancer Model Initiative). Sex at birth: female; Primary diagnosis: Serous surface papillary carcinoma; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: High Grade.
Specimen HCM-CSHL-0853-C56-85D: Sample type: Next Generation Cancer Model; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: 3D Organoid; Preservation method: Frozen; Passage count: 5.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 714751aa-d288-4feb-af15-71993aa27177.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator HCM-CSHL-0853-C56-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,235 have no estimate.
https://portal.gdc.cancer.gov/files/ed2b9d7f-4ec2-414a-bb1c-58f7c6fb24bb

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 1; copy number 2: 16,414; copy number 3: 10,178; copy number 4: 24,636; copy number 5: 2,712; copy number 6: 2,845; copy number 7: 397; copy number 8: 352; copy number 9: 125; copy number 10: 680; copy number 11: 48.

Homozygous deletions (total copy number 0; autosomes only): 1 gene in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:114,349,483–114,350,648, 1 gene (within-gene range 0–2): DNAJA1P4.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 848 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr6:74,530,248–75,206,053, 5 genes, copy number 9 (within-gene range 6–9): AL356277.3, AL356277.1, AL356277.2, AL356473.1, COL12A1.
- chr6:75,921,114–76,072,678, 1 gene, copy number 10 (within-gene range 6–10): IMPG1.
- chr6:76,092,834–76,092,940, 1 gene, copy number 10: RNU6-248P.
- chr8:91,909,738–145,066,685, 841 genes, copy number 9–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
